Somatic mutation profile of tumor specimen TCGA-GF-A4EO-06A (aliquot TCGA-GF-A4EO-06A-12D-A24R-08) from TCGA case TCGA-GF-A4EO, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 74.2 years (27,114 days).
Specimen TCGA-GF-A4EO-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9da1c1e-b09a-40eb-8242-39b825836962.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GF-A4EO-10A (Blood Derived Normal), aliquot TCGA-GF-A4EO-10A-01D-A24R-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edae1b8d-1eff-482a-8e05-7f949ef0ccf6

The open-access MAF lists 286 somatic variants for this specimen: 189 protein-altering or splice-affecting, 92 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 170, Silent 92, Nonsense Mutation 12, 3'UTR 2, Splice Region 2, Splice Site 2, In Frame Del 2, RNA 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- NEB | c.13705C>T p.R4569* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as rs754369875, CM1213409, COSV50859766; ClinVar: pathogenic; called by muse, mutect2
- TP63 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761885185, COSV53196562, COSV53210463; called by muse, mutect2, varscan2
- A2M | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.031); catalogued as rs1173054508, COSV59384139; called by muse, mutect2, varscan2
- ABCA12 | c.5926C>T p.Q1976* (on ENST00000272895 / NM_173076.3; = p.Q1658* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 18/186 reads (10%) | catalogued as COSV55952601; called by muse, mutect2
- ABCA12 | c.1258C>T p.P420S (on ENST00000272895 / NM_173076.3; = p.P102S on NM_015657.3) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1297612225, COSV55952615; called by muse, mutect2, varscan2
- ABL2 | c.1361C>T p.P454L (on ENST00000502732 / NM_007314.4; = p.P439L on NM_005158.5) | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61011961; called by muse, mutect2, varscan2
- ACSL4 | c.397C>T p.R133C (on ENST00000340800 / NM_022977.2; = p.R92C on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs753267653, COSV61613733; called by muse, mutect2, varscan2
- ADAM29 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867583067, COSV63661697; called by muse, mutect2, varscan2
- ADAMTS6 | c.2105G>A p.R702K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs780009571, COSV66857857; called by mutect2, varscan2
- ADCY9 | c.1555C>T p.L519F | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53572811; called by muse, mutect2, varscan2
- ADGRF2 | c.1630C>T p.L544F (on ENST00000296862 / NM_001368115.2; = p.L476F on NM_153839.7) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.989); catalogued as COSV57286358, COSV57287234; called by muse, mutect2, varscan2
- ADGRV1 | c.16718G>A p.R5573K | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV67980727; called by muse, mutect2, varscan2
- AFF1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV57118375; called by muse, mutect2, varscan2
- AFF1 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100321047, COSV57121558; called by muse, mutect2, varscan2
- AHI1 | c.3316G>A p.V1106M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55624552; called by muse, mutect2, varscan2
- ALCAM | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329320159, COSV60252439; called by muse, mutect2
- ANPEP | c.1357C>T p.H453Y | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55590068; called by muse, mutect2, varscan2
- AOPEP | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0.025); catalogued as rs771658703, COSV52915782; called by muse, mutect2, varscan2
- AQP10 | c.866A>C p.E289A | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV59245264; called by muse, mutect2, varscan2
- ARHGAP5 | c.2840A>C p.N947T | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as COSV61534464; called by muse, mutect2, varscan2
- ASPG | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs749790590, COSV71933650; called by muse, mutect2, varscan2
- ATRNL1 | c.3980C>T p.P1327L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782613375, COSV58078539; called by muse, mutect2
- BEND3 | c.379T>C p.Y127H | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.093); catalogued as COSV64680305; called by muse, mutect2, varscan2
- BMX | c.1903C>T p.H635Y | Missense Mutation (SNP) | VAF 18/237 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV59590625; called by muse, mutect2
- BRAF | c.547A>G p.K183E | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV56110289, COSV56243281; called by muse, mutect2, varscan2
- BRINP3 | c.740T>G p.L247R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66516988; called by muse, mutect2, varscan2
- BSN | c.5845C>T p.P1949S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs762937440, COSV56514621; called by muse, mutect2, varscan2
- C1orf127 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.979); catalogued as COSV65436734; called by muse, mutect2, varscan2
- CALCOCO2 | c.286T>C p.Y96H | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51951391; called by muse, mutect2
- CBLL2 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs867047847, COSV60368632; called by muse, mutect2
- CCDC60 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.316); catalogued as COSV59541562; called by muse, mutect2, varscan2
- CD93 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202080643, COSV55664001; called by muse, mutect2, varscan2
- CDRT1 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 28/291 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV55411468; called by muse, mutect2
- CEP120 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100071454; called by muse, mutect2, varscan2
- CFAP47 | c.4291G>A p.D1431N | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.113); catalogued as COSV57972139; called by muse, mutect2
- CFHR2 | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66380713; called by muse, mutect2, varscan2
- CFI | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 53/331 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67098105; called by muse, mutect2, varscan2
- CHI3L1 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.705); catalogued as rs896560392, COSV55137495; called by muse, mutect2, varscan2
- COL28A1 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV68081129; called by muse, mutect2, varscan2
- COL4A4 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.027); catalogued as COSV61630476; called by muse, mutect2, varscan2
- COL6A6 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.096); catalogued as COSV62016595, COSV62020386; called by muse, mutect2, varscan2
- CTNND2 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as COSV58873258; called by muse, mutect2, varscan2
- DEGS2 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.635); catalogued as COSV59783712, COSV99979202; called by muse, mutect2, varscan2
- DHX32 | c.1174C>T p.L392F | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV52938822; called by muse, mutect2, varscan2
- DIAPH3 | c.2629G>A p.D877N (on ENST00000400324 / NM_001042517.2; = p.D614N on NM_030932.3) | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748797648, COSV57366598; called by muse, mutect2, varscan2
- DNAH12 | c.503C>G p.S168W | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV60855640, COSV60856070; called by muse, mutect2, varscan2
- DNAH5 | c.11233C>T p.H3745Y | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV54208394; called by muse, mutect2
- DPP3 | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV64756291; called by muse, mutect2, varscan2
- DSC2 | c.334T>A p.F112I | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV51862340; called by muse, mutect2
- DSPP | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.208); catalogued as rs748231789, COSV56808854; called by muse, mutect2, varscan2
- EDNRA | c.1213A>G p.I405V | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs1368512467, COSV60096261, COSV60099873; called by muse, mutect2, varscan2
- EMC7 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as rs190604325, COSV56626848; called by muse, mutect2, varscan2
- EP300 | c.3595C>T p.H1199Y | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV54328922; called by muse, mutect2, varscan2
- EPC1 | c.2336G>A p.R779K | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV53923993, COSV99553303; called by muse, mutect2
- ERO1B | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1429068880, COSV51595398; called by muse, mutect2
- ESX1 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.445); catalogued as COSV65424066; called by muse, mutect2
- EXT2 | c.556C>T p.H186Y (on ENST00000343631; = p.H219Y on NM_000401.3) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59147872; called by muse, mutect2, varscan2
- EYA4 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.294); catalogued as rs184768806, COSV62047699; called by muse, mutect2, varscan2
- F8 | c.6680C>T p.A2227V | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM083813, COSV57704599, COSV57706407; called by muse, mutect2
- FAM135B | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50523657; called by muse, mutect2, varscan2
- FAM83B | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1451997050, COSV60920323; called by muse, mutect2, varscan2
- FAT2 | c.8438G>A p.G2813E | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55815600; called by muse, mutect2, varscan2
- FRMPD1 | c.4325T>C p.V1442A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs1374361748, COSV66699552; called by muse, mutect2, varscan2
- GABRG2 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.423); catalogued as rs1184632361, COSV62716186; called by muse, mutect2, varscan2
- GCC1 | c.62T>G p.I21R | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV50000517; called by muse, mutect2, varscan2
- GLI1 | c.3317C>T p.A1106V | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.158); catalogued as COSV57359366; called by muse, mutect2
- GLRA2 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.242); catalogued as COSV54337594; called by muse, mutect2, varscan2
- GPR35 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60576724; called by muse, mutect2, varscan2
- GRHL3 | c.1249C>T p.R417W (on ENST00000350501 / NM_198174.3; = p.R422W on NM_021180.3) | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs993460632, COSV99359291; called by muse, mutect2, varscan2
- GRIN2A | c.3965G>A p.G1322E | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.142); catalogued as COSV58021494; called by muse, mutect2, varscan2
- GRXCR2 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV65060832; called by muse, mutect2
- HCN1 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.014); catalogued as rs776567935, COSV57499129; called by muse, mutect2, varscan2
- HFM1 | c.3983C>T p.S1328L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV54023635; called by muse, mutect2
- HNF1A | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.334); catalogued as rs1330403052, COSV57460505; called by muse, mutect2
- HSD17B13 | c.673T>C p.F225L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.249); catalogued as COSV56345582; called by muse, mutect2, varscan2
- IARS1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as rs1386040072, COSV65114425; called by muse, mutect2, varscan2
- IGSF1 | c.3155C>G p.P1052R | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV63836643; called by muse, mutect2, varscan2
- IGSF9B | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58065050; called by muse, mutect2
- IRAG2 | c.3886C>T p.R1296* (on ENST00000636465; = p.R341* on NM_006152.4 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | catalogued as rs1005464919, COSV57229829; called by muse, mutect2, varscan2
- ITPR2 | c.6001C>T p.H2001Y | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV67266531; called by muse, mutect2, varscan2
- KALRN | c.7644C>A p.C2548* (on ENST00000360013 / NM_001024660.4; = p.C851* on NM_007064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/110 reads (10%) | catalogued as COSV52252071; called by muse, mutect2, varscan2
- KCNA6 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs866418364, COSV54974491; called by muse, mutect2, varscan2
- KIAA1614 | c.2164C>T p.Q722* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV62550525; called by muse, mutect2, varscan2
- KIF4B | c.1804C>T p.L602F | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70528436; called by muse, mutect2
- KRIT1 | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60667245; called by muse, mutect2, varscan2
- LAMA1 | c.7792C>T p.Q2598* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV67533665; called by muse, mutect2, varscan2
- LAMA2 | c.1785C>T p.L595= | Splice Region (SNP) | VAF 15/64 reads (23%) | catalogued as COSV70342367; called by muse, mutect2, varscan2
- LAMB4 | c.1474G>A p.G492R | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52715752; called by muse, mutect2, varscan2
- LMAN2 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.928); catalogued as COSV100288493; called by muse, mutect2, varscan2
- LMTK3 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV54310592; called by muse, mutect2, varscan2
- LRG1 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs775214650, COSV56702828; called by muse, mutect2, varscan2
- LRIG1 | c.2353G>T p.G785C | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.443); catalogued as COSV56238227; called by muse, mutect2
- LYN | c.179-1G>A p.X60_splice | Splice Site (SNP) | VAF 17/98 reads (17%) | catalogued as COSV72923022; called by muse, mutect2, varscan2
- MCM2 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1225895890, COSV54032594; called by muse, mutect2
- MIB1 | c.1507C>T p.H503Y | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.784); catalogued as COSV99839449; called by muse, mutect2, varscan2
- MLXIPL | c.419G>A p.S140N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.028); catalogued as rs1554598768, COSV57667245; called by muse, mutect2, varscan2
- MROH2B | c.4136G>A p.R1379Q | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as rs753433063, COSV68182217; called by muse, mutect2, varscan2
- MXRA5 | c.2353G>A p.D785N | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as rs760375645, COSV54228446; called by muse, mutect2, varscan2
- NEB | c.12049G>A p.G4017R | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50860000, COSV99417376; called by muse, mutect2
- NGEF | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV50915941; called by muse, mutect2, varscan2
- NLRP2 | c.1297C>T p.L433F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1268464888, COSV54753278; called by muse, mutect2, varscan2
- NPHP3 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as COSV58128956; called by muse, mutect2, varscan2
- NPLOC4 | c.739C>G p.Q247E | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100481215; called by muse, mutect2, varscan2
- OCLN | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 45/248 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62284918; called by muse, mutect2, varscan2
- OR13C5 | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV66164387; called by muse, mutect2, varscan2
- OR2F1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs748122563, COSV67331053; called by muse, mutect2, varscan2
- OR2H1 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV65810325; called by muse, mutect2
- OR2L3 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs879860810, COSV63454759; called by muse, mutect2, varscan2
- OR5H15 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62947322, COSV62947829; called by muse, mutect2, varscan2
- OR5H6 | c.718A>C p.T240P (on ENST00000642105; = p.T224P on NM_001005479.2) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67351196; called by muse, mutect2, varscan2
- OSGIN2 | c.1505A>T p.D502V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV52407578; called by muse, mutect2, varscan2
- PCDH15 | c.4565G>A p.R1522K (on ENST00000617271 / NM_001142770.3; = p.K1510= on NM_001142769.3) | Missense Mutation (SNP) | VAF 17/161 reads (11%) | PolyPhen benign (0.006); catalogued as COSV64680988; called by muse, mutect2
- PCDHA1 | c.1079G>A p.R360K | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.067); catalogued as COSV65373194; called by muse, mutect2, varscan2
- PCDHA7 | c.1411G>A p.G471S | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100971970, COSV65342786; called by muse, mutect2, varscan2
- PCSK5 | c.2510+1G>A p.X837_splice | Splice Site (SNP) | VAF 20/100 reads (20%) | catalogued as COSV65085391; called by muse, mutect2, varscan2
- PDE1C | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.094); catalogued as rs1319976029, COSV58506678; called by muse, mutect2, varscan2
- PDE5A | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.074); catalogued as rs200040534, COSV53346233; called by muse, mutect2, varscan2
- PDPR | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.029); catalogued as rs1322970132, COSV55350180; called by muse, mutect2, varscan2
- PKDREJ | c.5407G>A p.E1803K | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV53547398; called by muse, mutect2, varscan2
- PKP3 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1484468177, COSV58986364; called by muse, mutect2
- PODXL | c.1516G>A p.G506S (on ENST00000378555 / NM_001018111.3; = p.G474S on NM_005397.4) | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367940971, COSV59869072; called by muse, mutect2, varscan2
- POLR1A | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.338); catalogued as COSV55690539; called by muse, mutect2
- PPARGC1B | c.2077G>T p.D693Y | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV58527289; called by muse, mutect2, varscan2
- PRAMEF4 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 71/392 reads (18%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV52437756; called by muse, mutect2, varscan2
- PRPS1 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 27/293 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV65054190; called by muse, mutect2
- PTDSS2 | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV57277505; called by muse, mutect2
- QRICH2 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 15/227 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as rs774220097, COSV53151726, COSV53153695; called by muse, mutect2
- RAG1 | c.2855G>T p.R952M | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55024326; called by muse, mutect2
- RASAL2 | c.2267C>T p.P756L | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV62711307; called by muse, mutect2, varscan2
- RASSF7 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60346230; called by muse, mutect2, varscan2
- RBFOX1 | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV60950758, COSV60953135; called by muse, mutect2, varscan2
- RBL1 | c.2324A>G p.H775R | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs752745837, COSV60328895; called by muse, mutect2, varscan2
- RBM33 | c.2060C>T p.S687F | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1464514092, COSV56630187; called by muse, mutect2, varscan2
- RESF1 | c.2960A>G p.E987G | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV57020426; called by muse, mutect2, varscan2
- RGS3 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as COSV58278191; called by muse, mutect2, varscan2
- RIMBP2 | c.1576G>T p.G526C | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55467698; called by muse, mutect2, varscan2
- RPH3A | c.1595G>A p.R532Q (on ENST00000389385 / NM_001143854.2; = p.R528Q on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/258 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs748807513, COSV66990333; called by muse, mutect2
- RSRC1 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV99907130; called by muse, mutect2
- RTL9 | c.586C>A p.L196I | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV71825453; called by muse, mutect2, varscan2
- RXFP2 | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.105); catalogued as COSV53633987; called by muse, mutect2, varscan2
- SALL3 | c.2977G>A p.E993K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.197); catalogued as COSV73305868, COSV73306320; called by muse, mutect2, varscan2
- SCARF2 | c.2078C>T p.S693F | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.149); catalogued as COSV56731382; called by muse, mutect2, varscan2
- SCN1A | c.5179G>A p.D1727N (on ENST00000303395 / NM_001202435.3; = p.D1716N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV57664108; called by muse, mutect2, varscan2
- SFRP5 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV56603860, COSV56605202; called by muse, mutect2, varscan2
- SLC35G2 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV67587989; called by muse, mutect2, varscan2
- SLC38A4 | c.923A>C p.D308A | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV56965809; called by muse, mutect2, varscan2
- SLC4A1 | c.1758G>A p.M586I | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV52259016; called by muse, mutect2, varscan2
- SLCO2A1 | c.759G>A p.W253* | Nonsense Mutation (SNP) | VAF 16/105 reads (15%) | catalogued as COSV60484287; called by muse, mutect2, varscan2
- SMARCD2 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV56738330; called by muse, mutect2, varscan2
- SNX2 | c.248T>C p.L83S | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.395); catalogued as COSV65347858; called by muse, mutect2, varscan2
- ST6GAL2 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 33/194 reads (17%) | PolyPhen benign (0.005); catalogued as rs746454620, COSV100868284; called by muse, mutect2, varscan2
- STAB2 | c.3039G>A p.W1013* | Nonsense Mutation (SNP) | VAF 13/117 reads (11%) | catalogued as COSV66336200; called by muse, mutect2, varscan2
- STK38L | c.982C>A p.P328T | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV66520871; called by muse, mutect2, varscan2
- STXBP5L | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1438979258, COSV56505074; called by muse, mutect2
- TBC1D23 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100792749; called by muse, mutect2, varscan2
- TBC1D32 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs374512287; called by muse, mutect2, varscan2
- TBC1D5 | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV53752116; called by muse, mutect2
- TBX20 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101282424, COSV68783025; called by muse, mutect2
- TC2N | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1384224520, COSV61746482; called by muse, mutect2, varscan2
- TERT | c.3284C>G p.S1095* | Nonsense Mutation (SNP) | VAF 6/113 reads (5%) | catalogued as COSV57205142; called by muse, mutect2
- TG | c.5930C>T p.S1977F | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs748239110, COSV55069363; called by muse, mutect2, varscan2
- TLL1 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); catalogued as rs1411322301, COSV50261775; called by muse, mutect2
- TM7SF3 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 16/135 reads (12%) | catalogued as COSV100545080, COSV58001712; called by muse, mutect2, varscan2
- TMC7 | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58582225; called by muse, mutect2, varscan2
- TMC8 | c.1669C>T p.H557Y | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.185); catalogued as COSV59208962; called by muse, mutect2, varscan2
- TMEFF2 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55829615; called by muse, mutect2, varscan2
- TNKS2 | c.2697C>T p.I899= | Splice Region (SNP) | VAF 11/65 reads (17%) | catalogued as rs751359159, COSV65415005; called by muse, mutect2
- TRAPPC10 | c.1630C>T p.L544F | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52376109; called by muse, mutect2
- TRAV20 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs541627530; called by muse, mutect2, varscan2
- TSPAN12 | c.737G>T p.W246L | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as COSV56078921, COSV99763247; called by muse, mutect2
- TTN | c.98849G>A p.R32950Q (on ENST00000591111; = p.R25526Q on NM_003319.4) | Missense Mutation (SNP) | VAF 7/69 reads (10%) | PolyPhen probably damaging (0.996); catalogued as rs778021095, COSV59942263; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TTN | c.70166C>T p.P23389L (on ENST00000591111; = p.P15965L on NM_003319.4) | Missense Mutation (SNP) | VAF 24/166 reads (14%) | PolyPhen probably damaging (0.999); catalogued as COSV59942303; called by muse, mutect2, varscan2
- TTYH2 | c.932C>T p.T311I | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV53909300; called by muse, mutect2, varscan2
- USF2 | c.733C>G p.R245G | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55885166; called by muse, mutect2, varscan2
- USHBP1 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1209899847, COSV53102653; called by muse, mutect2
- VPS13D | c.11717C>T p.T3906I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs766283495, COSV50627033; called by muse, mutect2, varscan2
- ZDBF2 | c.3013G>T p.G1005C | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV65623124; called by muse, mutect2, varscan2
- ZNF205 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54620324; called by muse, mutect2
- ZNF329 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs778423178, COSV63771919; called by muse, mutect2, varscan2
- ZNF638 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as COSV100039938; called by muse, mutect2, varscan2
- CWC25 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- HERC1 | c.9215_9220del p.V3072_Y3073del | In Frame Del (DEL) | VAF 11/65 reads (17%) | called by mutect2, pindel, varscan2
- IGHV4-28 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.296); called by muse, varscan2
- KLF6 | c.13_15del p.P5del | In Frame Del (DEL) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.3146C>T p.S1049F (on ENST00000621492; = p.S1015F on NM_025248.3) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TMEM185A | c.998G>A p.S333N | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.404); called by muse, mutect2
- TRIM37 | c.2368_2371dup p.Q791Lfs*6 | Frame Shift Ins (INS) | VAF 19/116 reads (16%) | called by mutect2, pindel, varscan2
- XAGE2 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AC100868.1 | c.1515C>T p.F505= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV51839826; called by muse, mutect2, varscan2
- ACTN2 | c.528C>T p.F176= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as COSV63973245; called by muse, mutect2, varscan2
- AOC1 | c.876C>T p.P292= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs375861624, COSV62867514, COSV62870764; called by muse, mutect2, varscan2
- ARHGAP20 | c.1002C>T p.I334= | Silent (SNP) | VAF 31/144 reads (22%) | catalogued as COSV52808174; called by muse, mutect2, varscan2
- ARHGAP32 | c.3921C>T p.P1307= (on ENST00000310343 / NM_001378025.1; = p.P958= on NM_014715.4) | Silent (SNP) | VAF 26/139 reads (19%) | catalogued as COSV59844672; called by muse, mutect2, varscan2
- ATP2A3 | c.2619C>T p.F873= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV59227245; called by muse, mutect2, varscan2
- AUTS2 | c.2541C>T p.V847= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs754540807, COSV61389191; called by muse, mutect2, varscan2
- BACH2 | c.1044G>A p.T348= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs267601167, COSV57587428; called by muse, mutect2, varscan2
- BROX | c.1233C>T p.S411= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV61799024; called by muse, mutect2
- C1QTNF1 | c.501C>T p.F167= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as rs777218254, COSV59261139; ClinVar: likely benign; called by muse, mutect2, varscan2
- C1QTNF7 | c.549G>A p.G183= | Silent (SNP) | VAF 59/287 reads (21%) | catalogued as COSV54851257; called by muse, mutect2, varscan2
- CARMIL2 | c.1035G>A p.G345= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1412689704, COSV58024296; called by muse, mutect2, varscan2
- CHRM2 | c.126C>T p.I42= | Silent (SNP) | VAF 42/130 reads (32%) | catalogued as COSV57767921; called by muse, mutect2, varscan2
- CLDN1 | c.561C>T p.P187= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV55043633; called by muse, mutect2, varscan2
- COL26A1 | c.594G>A p.T198= (on ENST00000313669 / NM_001278563.3; = p.T196= on NM_133457.4) | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs763064174, COSV58121987; called by muse, mutect2, varscan2
- CRNN | c.1464C>T p.S488= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs750968936, COSV55121194; called by muse, mutect2, varscan2
- CYP4F11 | c.858C>T p.F286= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as COSV56126107; called by muse, mutect2, varscan2
- DNAH1 | c.5796G>A p.R1932= | Silent (SNP) | VAF 27/198 reads (14%) | catalogued as COSV70227262; called by muse, mutect2, varscan2
- DOLPP1 | c.243G>A p.Q81= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV59910130; called by muse, mutect2, varscan2
- DOP1A | c.2379T>G p.T793= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV52708123; called by muse, mutect2, varscan2
- EPG5 | c.7422G>A p.R2474= | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as rs1036226828, COSV56346496; called by muse, mutect2, varscan2
- FAM153A | c.411G>A p.G137= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV62361258; called by muse, mutect2, varscan2
- FANCA | c.4146G>A p.R1382= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs759216137, COSV57066827; called by muse, mutect2, varscan2
- FCGBP | c.9399C>T p.A3133= | Silent (SNP) | VAF 14/207 reads (7%) | catalogued as rs572782761; called by muse, mutect2
- FLNC | c.6630C>T p.S2210= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs376657814, COSV57952531; called by muse, mutect2, varscan2
- FNDC7 | c.1098C>T p.F366= | Silent (SNP) | VAF 26/149 reads (17%) | catalogued as COSV54751714; called by muse, mutect2, varscan2
- GAA | c.1401C>T p.F467= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV56407531; called by muse, mutect2, varscan2
- GAL3ST1 | c.390G>A p.R130= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV58892075; called by muse, mutect2, varscan2
- GLP1R | c.921C>T p.L307= | Silent (SNP) | VAF 36/227 reads (16%) | catalogued as COSV64714570; called by muse, mutect2, varscan2
- GOLGB1 | c.8502T>C p.F2834= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV61463170; called by muse, mutect2, varscan2
- GRHL3 | c.1248C>T p.F416= (on ENST00000350501 / NM_198174.3; = p.F421= on NM_021180.3) | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as rs374698640, COSV99359680; called by muse, mutect2, varscan2
- HECA | c.825G>A p.T275= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1342172981, COSV62768712; called by muse, mutect2, varscan2
- HEXIM1 | c.136A>C p.R46= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as COSV60176787; called by muse, mutect2
- HEXIM2 | c.420C>A p.P140= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV56236002; called by muse, mutect2, varscan2
- HHIPL1 | c.1590C>T p.F530= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as COSV58089610; called by muse, mutect2, varscan2
- ITGA8 | c.1749C>T p.F583= | Silent (SNP) | VAF 42/259 reads (16%) | catalogued as COSV65225246; called by muse, mutect2, varscan2
- KAT6A | c.4482C>T p.V1494= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV55904223; called by muse, mutect2, varscan2
- KIDINS220 | c.4398C>T p.S1466= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV56751436; called by muse, mutect2, varscan2
- KIF17 | c.1659C>T p.F553= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV56116767; called by muse, mutect2, varscan2
- KRT2 | c.720G>A p.L240= | Silent (SNP) | VAF 14/161 reads (9%) | catalogued as rs1411515180, COSV59009576; called by muse, mutect2
- LCT | c.3639C>T p.I1213= | Silent (SNP) | VAF 17/173 reads (10%) | catalogued as rs940172090, COSV51545793; called by muse, mutect2, varscan2
- LILRB1 | c.903C>T p.F301= (on ENST00000427581; = p.F265= on NM_006669.6) | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as COSV61116452, COSV61116772, COSV61122370; called by muse, mutect2, varscan2
- LPCAT1 | c.306C>T p.I102= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV52036217; called by muse, mutect2, varscan2
- LRRC37A3 | c.3978G>A p.K1326= | Silent (SNP) | VAF 41/276 reads (15%) | catalogued as COSV58534619; called by muse, mutect2, varscan2
- MGAT5 | c.567C>T p.L189= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as rs951757005, COSV56094820; called by muse, mutect2, varscan2
- MMUT | c.714C>T p.S238= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs1489344185, COSV51272637; called by muse, mutect2, varscan2
- MRO | c.45C>T p.I15= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV99839548; called by muse, mutect2, varscan2
- MS4A14 | c.1719G>A p.G573= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV55733735; called by muse, mutect2, varscan2
- MTPAP | c.696C>T p.S232= | Silent (SNP) | VAF 58/257 reads (23%) | catalogued as rs780929371, COSV53931921; called by muse, mutect2, varscan2
- NEK10 | c.2007A>C p.V669= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV58281259; called by muse, mutect2
- NFATC2IP | c.1176C>T p.F392= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV57909911; called by muse, mutect2, varscan2
- NISCH | c.678C>T p.H226= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs774736200, COSV61898958; called by muse, mutect2
- NLGN4X | c.1755G>A p.T585= | Silent (SNP) | VAF 17/204 reads (8%) | catalogued as rs1223422972, COSV52008650; called by muse, mutect2
- NOTCH4 | c.4797A>G p.E1599= | Silent (SNP) | VAF 4/57 reads (7%) | catalogued as COSV66679506; called by muse, mutect2
- NPLOC4 | c.738C>T p.N246= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100481216; called by muse, mutect2, varscan2
- NRG3 | c.1011C>T p.S337= | Silent (SNP) | VAF 4/71 reads (6%) | catalogued as COSV64550463; called by muse, mutect2
- NUP54 | c.855A>G p.R285= | Silent (SNP) | VAF 8/226 reads (4%) | catalogued as rs1177526257, COSV53574855; called by muse, mutect2
- OR4C11 | c.789C>T p.F263= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as rs1436619879, COSV56352400; called by muse, mutect2, varscan2
- OR4S2 | c.295C>T p.L99= | Silent (SNP) | VAF 51/171 reads (30%) | catalogued as COSV56746246; called by muse, mutect2, varscan2
- OR51A2 | c.711G>A p.K237= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV66748202; called by muse, mutect2, varscan2
- OR51A7 | c.405C>T p.I135= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV63788115; called by muse, mutect2
- OR8D2 | c.39C>T p.I13= | Silent (SNP) | VAF 21/155 reads (14%) | catalogued as COSV62488246; called by muse, mutect2, varscan2
- OSMR | c.1206G>A p.A402= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as rs774204835, COSV57082388; called by muse, mutect2, varscan2
- PANX3 | c.801C>T p.S267= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV52511425, COSV52514150; called by muse, mutect2, varscan2
- PCDHAC2 | c.1512G>A p.V504= | Silent (SNP) | VAF 28/164 reads (17%) | catalogued as COSV53841148; called by muse, mutect2, varscan2
- PCDHB10 | c.1161G>A p.E387= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV53376559; called by muse, mutect2, varscan2
- PHEX | c.1668G>A p.Q556= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV65074403; called by muse, mutect2, varscan2
- PKHD1 | c.5943C>T p.I1981= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as rs768329869, COSV61865805; called by muse, mutect2, varscan2
- PLAGL1 | c.204G>A p.E68= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV52785899; called by muse, mutect2, varscan2
- POLA2 | c.1333C>T p.L445= | Silent (SNP) | VAF 77/345 reads (22%) | catalogued as rs902322318, COSV55481532; called by muse, mutect2, varscan2
- PSG6 | c.1047C>T p.L349= | Silent (SNP) | VAF 21/347 reads (6%) | catalogued as rs768478328, COSV51831110, COSV51835705; called by muse, mutect2
- RYR3 | c.8505C>T p.A2835= (on ENST00000389232; = p.A2836= on NM_001036.6) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV66781872; called by muse, mutect2
- SCN4A | c.777C>T p.F259= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as COSV71126039; called by muse, mutect2, varscan2
- SIPA1L3 | c.3486C>T p.S1162= | Silent (SNP) | VAF 53/302 reads (18%) | catalogued as COSV55910674; called by muse, mutect2, varscan2
- SLC13A3 | c.1413C>T p.I471= | Silent (SNP) | VAF 21/180 reads (12%) | catalogued as COSV51713040, COSV51721835; called by muse, mutect2, varscan2
- SLC24A3 | c.1548C>T p.F516= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV60114784; called by muse, mutect2
- SLC35B4 | c.375C>T p.A125= | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as COSV65984470; called by muse, mutect2, varscan2
- SLCO1B1 | c.387C>T p.I129= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV57008544; called by muse, mutect2, varscan2
- SNX5 | c.1092C>T p.F364= | Silent (SNP) | VAF 43/196 reads (22%) | catalogued as COSV66697677; called by muse, mutect2, varscan2
- SPIN2B | c.741C>T p.F247= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV52068786; called by muse, mutect2
- ST14 | c.2175C>T p.S725= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV53832169; called by muse, mutect2, varscan2
- ST6GAL2 | c.459C>T p.P153= | Silent (SNP) | VAF 33/194 reads (17%) | catalogued as rs142520495, COSV64529387; called by muse, mutect2, varscan2
- SV2A | c.1863G>A p.K621= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV64964454; called by muse, mutect2, varscan2
- TAS2R13 | c.327C>A p.L109= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV66831513; called by muse, mutect2, varscan2
- TCEAL9 | c.117C>T p.A39= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as rs747096739, COSV101012055, COSV65488939; called by muse, mutect2, varscan2
- TECTA | c.1911C>T p.F637= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as rs368109045; called by muse, mutect2
- THBS4 | c.2349G>A p.G783= | Silent (SNP) | VAF 15/111 reads (14%) | catalogued as COSV63468120; called by muse, mutect2, varscan2
- TRIM14 | c.639G>A p.K213= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as rs1255202596, COSV58353575; called by muse, mutect2, varscan2
- TSC2 | c.1014C>T p.I338= | Silent (SNP) | VAF 48/165 reads (29%) | catalogued as rs1250621196, COSV54759435; called by muse, mutect2, varscan2
- VGLL1 | c.714G>A p.G238= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV101034724; called by muse, mutect2
- ZNF638 | c.1815A>T p.S605= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV100039928; called by muse, mutect2, varscan2
- ZNF678 | c.1212C>T p.P404= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV59381059; called by muse, mutect2, varscan2
- BTN1A1 | c.*2G>A | 3'UTR (SNP) | VAF 18/105 reads (17%) | catalogued as rs756787393, COSV55069005; called by muse, mutect2, varscan2
- CLASP1 | c.2734-773A>T | Intron (SNP) | VAF 18/159 reads (11%) | catalogued as COSV99757165; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.846C>T | RNA (SNP) | VAF 17/68 reads (25%) | catalogued as rs1555901801; called by muse, mutect2, varscan2
- MIR522 | n.64C>T | RNA (SNP) | VAF 21/92 reads (23%) | catalogued as rs757377349; called by muse, mutect2, varscan2
- SERTM1 | c.*2G>A | 3'UTR (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100171498; called by muse, mutect2, varscan2
